Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PT, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PT-01A (Primary Tumor).

ICD O 3
Adenocarcinoma, intestinal type
814413
Site Body & stomach
C16.2
JW 3/7/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

1- "Chain 1 lymph node": fibrous connective tissue uninvolved by neoplasia.

2- "Stomach + Omentum + Transverse colon (product of subtotal gastrectomy + partial oophorectomy + D2 lymphadenectomy":

Poorly differentiated adenocarcinoma intestinal type of Lauren:

- . Size in major axis: 7.4 cm.
- . Ulceration: present.
- . Infiltration of mucosa, submucosa, muscularis propria, mesenteric fat.
- . Adherence to the colon without neoplastic infiltration.
- . Neural infiltration not detected.
- . Lymphatic vascular invasion not detected.
- . Blood vascular invasion not detected.
- . Discrete peritumoral inflammatory reaction.
- . Absence of desmoplasia.
- . Lymph nodes dissected uninvolved by neoplasia along the piece (0/35).

3- "8a lymph node": uninvolved by neoplasia.

4- "11p lymph node": uninvolved by neoplasia.

5- "8p lymph node": uninvolved by neoplasia.

6- "Gastric margin": uninvolved by neoplasia.

Pathological Staging: pT4 pN0

Metastasis Discrepancy		☒

Source: NCI Genomic Data Commons file 1e136f9a-20c9-4b6d-9e48-640dd47883c6 (TCGA-VQ-A8PT.A2619FE5-016D-40D9-8464-1DA0CE8D2206.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).